Somatic mutation profile of tumor specimen TCGA-BK-A6W4-01A (aliquot TCGA-BK-A6W4-01A-12D-A34Q-09) from TCGA case TCGA-BK-A6W4, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 62.3 years (22,766 days).
Specimen TCGA-BK-A6W4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 106a62c1-c03b-4da7-a292-20c67902d209.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BK-A6W4-10A (Blood Derived Normal), aliquot TCGA-BK-A6W4-10A-01D-A34Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8eeb5bdc-47c5-49f9-a1b4-4e17debce5a9

The open-access MAF lists 21 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, Nonsense Mutation 2, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4337G>A p.R1446H | Missense Mutation (SNP) | VAF 6/105 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519884, COSV52112787, COSV52125401, COSV52132241; ClinVar: likely pathogenic; called by muse, mutect2
- PTEN | c.548dup p.N184Efs*6 | Frame Shift Ins (INS) | VAF 6/33 reads (18%) | catalogued as rs1554900593, COSV64296770; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- C2CD3 | c.814C>A p.L272M | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.388); catalogued as COSV100486888; called by muse, mutect2
- GGCT | c.211A>G p.I71V | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.465); catalogued as COSV99139185; called by muse, mutect2
- KCNA6 | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1303120890, COSV99768712; called by muse, mutect2
- MAPT | c.163G>A p.G55R | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.562); catalogued as rs1012826460, CM139631, COSV99290687; called by muse, mutect2
- PCDHA1 | c.1390G>A p.V464M | Missense Mutation (SNP) | VAF 7/159 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as COSV65373216; called by muse, mutect2
- PIK3R1 | c.1600C>T p.R534* (on ENST00000521381 / NM_181523.3; = p.R264* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 12/96 reads (13%) | catalogued as COSV57137455; called by muse, mutect2
- SIN3A | c.2119C>T p.R707* | Nonsense Mutation (SNP) | VAF 8/68 reads (12%) | catalogued as COSV64581720; called by muse, varscan2
- SORCS1 | c.3263C>T p.A1088V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.241); catalogued as rs758327035, COSV53868999; called by mutect2, varscan2
- SVEP1 | c.5644G>A p.D1882N | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV99929228; called by mutect2, varscan2
- TBL1X | c.119T>G p.F40C | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as COSV99482705; called by muse, mutect2
- TTC3 | c.4529A>G p.Y1510C | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1300206366, COSV100695659; called by muse, mutect2
- TTK | c.1806G>A p.M602I | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100036364; called by muse, mutect2
- ZXDB | c.1753G>T p.A585S | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100885951; called by muse, mutect2
- ANK1 | c.2542C>T p.P848S | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0.011); called by muse, mutect2
- CSMD3 | c.8355C>T p.C2785= (on ENST00000297405 / NM_001363185.1; = p.C2616= on NM_052900.3) | Silent (SNP) | VAF 5/62 reads (8%) | catalogued as rs1258675208, COSV99836967; called by muse, mutect2
- DCAF1 | c.4335C>T p.N1445= | Silent (SNP) | VAF 9/91 reads (10%) | catalogued as rs1553625537; called by muse, mutect2
- PCDHA12 | c.1683C>T p.N561= | Silent (SNP) | VAF 5/77 reads (6%) | catalogued as COSV56525703; called by muse, mutect2
- PCDHA7 | c.2073C>T p.T691= | Silent (SNP) | VAF 6/107 reads (6%) | catalogued as rs563748429, COSV100970776, COSV100970809, COSV65335403; called by muse, mutect2
- LRP5L | n.432T>C | RNA (SNP) | VAF 7/74 reads (9%) | called by muse, mutect2, varscan2
